CCDI case PBCGMP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/dfad70c6-e284-4883-8d4f-aa5f4d777cb3

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 11.8 years (4,318 days).

Biospecimens (3 samples)
- Sample 0DRL0P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRL0Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRL1N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
